Gene-level copy-number profile of tumor specimen TCGA-D1-A179-01A from TCGA case TCGA-D1-A179, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 76.8 years (28,037 days).
Specimen TCGA-D1-A179-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.808b6fb6-14d6-4f7d-b0b9-4550d76ff2f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A179-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c308ef8d-f903-4568-9d6d-16cbf1df428a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,292; copy number 2: 38,891; copy number 3: 2,208; copy number 4: 302; copy number 5: 40; copy number 6: 51; copy number 7: 6; copy number 8: 6; copy number 13: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A179-01A-11D-A12G-01): tumor purity 0.91, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 105 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,040,140–46,819,413, 30 genes, copy number 6: PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1, CYP4B1.
- chr2:112,541,915–113,496,204, 34 genes, copy number 5–7 (within-gene range 2–7): POLR1B, Y_RNA, CHCHD5, AC012442.2, AC012442.1, AC079922.1, AC079922.2, SLC20A1, NT5DC4, CKAP2L, IL1A, AC079753.2, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2.
- chr3:66,133,610–67,225,527, 11 genes, copy number 6–13 (within-gene range 3–13): SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1, RPL21P41, AC098969.2, AC098969.1, AC020655.1, KBTBD8, MIR4272.
- chr9:129,321,016–129,584,556, 11 genes, copy number 5: C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3, AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2, AL391056.1.
- chr9:129,612,225–129,620,776, 1 gene, copy number 5: C9orf50.
- chr14:76,826,372–77,225,462, 16 genes, copy number 6 (within-gene range 2–6): LRRC74A, RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2.
- chr14:77,131,270–77,142,996, 2 genes, copy number 6: ZDHHC22, AC007375.3.

Autosomal genes at a single copy (total copy number 1): 18,292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
